Somatic mutation profile of tumor specimen 0E1UJQ from CCDI case PBCWSH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male.
Specimen 0E1UJQ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2e07cefc-2427-4aa9-8700-d50af592777d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0E1UIW (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eaeaa588-74ee-4326-bdf2-9c8dff4146e4

The open-access MAF lists 30 somatic variants for this specimen: 16 protein-altering or splice-affecting, 8 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 8, Intron 4, 5'UTR 1, Translation Start Site 1, Nonsense Mutation 1, Splice Region 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CD177 | c.718G>T p.V240L | Missense Mutation (SNP) | VAF 52/220 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs763983308; called by muse, mutect2, varscan2
- GLCCI1 | c.1274G>A p.R425Q | Missense Mutation (SNP) | VAF 251/610 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as rs1280858437, COSV56205799; called by muse, mutect2, varscan2
- LRRC6 | c.682C>T p.Q228* | Nonsense Mutation (SNP) | VAF 235/571 reads (41%) | catalogued as rs1170838072; called by muse, mutect2, varscan2
- PGLYRP4 | c.354C>A p.N118K | Missense Mutation (SNP) | VAF 121/260 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.794); catalogued as COSV62834989; called by muse, mutect2, varscan2
- PRMT5 | c.1696+7G>T | Splice Region (SNP) | VAF 63/243 reads (26%) | catalogued as COSV99362917; called by muse, mutect2, varscan2
- TMEM255B | c.565G>A p.V189M | Missense Mutation (SNP) | VAF 24/333 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1463226310, COSV100943275; called by muse, mutect2
- C6orf47 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 98/142 reads (69%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.445); called by muse, mutect2, varscan2
- DNAH3 | c.5903A>G p.N1968S | Missense Mutation (SNP) | VAF 77/418 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- EMC2 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 252/584 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.114); called by muse, varscan2
- IL5RA | c.236C>A p.T79N | Missense Mutation (SNP) | VAF 269/287 reads (94%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- MBD4 | c.425A>G p.D142G | Missense Mutation (SNP) | VAF 277/593 reads (47%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MYB | c.1198G>T p.D400Y | Missense Mutation (SNP) | VAF 39/261 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- PER2 | c.3358G>A p.G1120S | Missense Mutation (SNP) | VAF 124/573 reads (22%) | SIFT tolerated (0.8); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- PRR30 | c.914G>A p.G305D | Missense Mutation (SNP) | VAF 110/257 reads (43%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- SBF2 | c.1495G>T p.A499S | Missense Mutation (SNP) | VAF 232/391 reads (59%) | SIFT tolerated (0.68); PolyPhen benign (0); called by mutect2, varscan2
- TMEM132C | c.299G>T p.G100V | Missense Mutation (SNP) | VAF 129/593 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACP2 | c.91C>A p.R31= | Silent (SNP) | VAF 94/320 reads (29%) | called by muse, mutect2, varscan2
- AQP7 | c.246G>T p.V82= | Silent (SNP) | VAF 49/184 reads (27%) | called by muse, mutect2, varscan2
- CFAP74 | c.4686G>T p.L1562= | Silent (SNP) | VAF 120/132 reads (91%) | called by muse, mutect2, varscan2
- COPE | c.39C>T p.S13= | Silent (SNP) | VAF 70/220 reads (32%) | catalogued as rs1191559351; called by muse, mutect2, varscan2
- DNAH7 | c.11406G>A p.S3802= | Silent (SNP) | VAF 221/529 reads (42%) | catalogued as rs765905199, COSV56776875; called by muse, mutect2, varscan2
- LZTS1 | c.1075C>T p.L359= | Silent (SNP) | VAF 150/315 reads (48%) | called by muse, mutect2, varscan2
- PARP3 | c.399C>A p.T133= | Silent (SNP) | VAF 86/226 reads (38%) | catalogued as COSV51753982, COSV99232354; called by mutect2, varscan2
- TCP11 | c.66G>A p.K22= | Silent (SNP) | VAF 71/316 reads (22%) | called by muse, mutect2, varscan2
- APOA2 | c.53-43T>A | Intron (SNP) | VAF 23/364 reads (6%) | catalogued as rs1266870418; called by muse, mutect2
- EFHC1 | c.1138-25C>A | Intron (SNP) | VAF 70/211 reads (33%) | called by muse, mutect2, varscan2
- HNRNPCL2 | c.-70T>A | 5'UTR (SNP) | VAF 30/34 reads (88%) | called by muse, mutect2, varscan2
- LAMB2 | c.4225-23C>A | Intron (SNP) | VAF 40/105 reads (38%) | called by muse, mutect2, varscan2
- OGFOD2 | c.190-156G>T | Intron (SNP) | VAF 15/64 reads (23%) | called by muse, mutect2, varscan2
- SLC4A11 | chr20:3237974 C>G | 5'Flank (SNP) | VAF 91/201 reads (45%) | called by muse, mutect2, varscan2
